Somatic mutation profile of tumor specimen TCGA-ZS-A9CD-01A (aliquot TCGA-ZS-A9CD-01A-11D-A36X-10) from TCGA case TCGA-ZS-A9CD, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 73.7 years (26,915 days).
Specimen TCGA-ZS-A9CD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de33f102-28f1-4162-8592-f8d62ad1ce94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZS-A9CD-10A (Blood Derived Normal), aliquot TCGA-ZS-A9CD-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b99f7e78-9ccb-4b97-ae49-ea53f4433724

The open-access MAF lists 104 somatic variants for this specimen: 78 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 24, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 1, Splice Site 1, RNA 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6260G>A p.G2087E | Missense Mutation (SNP) | VAF 27/98 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253928, COSV61375511; called by muse, mutect2, varscan2
- ACTN1 | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51995318; called by muse, mutect2, varscan2
- ATG5 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100576584; called by muse, mutect2
- ATP8A2 | c.3473G>T p.G1158V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99682433; called by muse, mutect2, varscan2
- C10orf88 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100925028; called by muse, mutect2, varscan2
- CD6 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100533069; called by muse, mutect2, varscan2
- CENPF | c.4444C>T p.P1482S | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100871729; called by muse, mutect2, varscan2
- CFAP47 | c.845G>C p.W282S | Missense Mutation (SNP) | VAF 102/186 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99935278; called by muse, mutect2, varscan2
- CNGA3 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs376992789; called by muse, mutect2, varscan2
- CNTN1 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100751530, COSV104418048; called by muse, mutect2, varscan2
- DISP2 | c.2446T>C p.C816R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99140105; called by muse, mutect2, varscan2
- E2F7 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV100523583; called by muse, mutect2, varscan2
- E2F8 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1004466044, COSV100001634; called by muse, mutect2
- ELF1 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs538458962, COSV99523130; called by muse, mutect2, varscan2
- EPHA7 | c.1910G>C p.R637P | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100993883, COSV100994557, COSV65184421; called by muse, mutect2, varscan2
- ERLIN1 | c.107A>T p.Y36F | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV100957159; called by muse, varscan2
- FASTKD2 | c.1388A>C p.Y463S | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99379038; called by muse, mutect2, varscan2
- FNDC1 | c.2197C>T p.Q733* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99796067; called by muse, mutect2, varscan2
- FUT3 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV99744689; called by muse, mutect2, varscan2
- FUT9 | c.1009G>C p.A337P | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100133782, COSV56146437; called by muse, mutect2
- GABRB2 | c.1032G>T p.K344N | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); catalogued as COSV99196183; called by muse, mutect2, varscan2
- GIGYF1 | c.1646A>G p.E549G | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99309548; called by muse, mutect2, varscan2
- GRIN2A | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs769971551, COSV100410167, COSV58044079; ClinVar: likely benign; called by muse, mutect2, varscan2
- HTT | c.5756T>G p.L1919R | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100750877; called by muse, mutect2, varscan2
- IGHV3-23 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.48); catalogued as rs552323116; called by muse, mutect2, varscan2
- JPT1 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as rs750053454, COSV99823959; called by muse, mutect2, varscan2
- KALRN | c.4603G>A p.E1535K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99565107; called by muse, mutect2, varscan2
- KCNC4 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV100873637; called by muse, mutect2, varscan2
- KCNU1 | c.589T>C p.F197L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101299278; called by muse, mutect2, varscan2
- KIAA0100 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.223); catalogued as COSV101197339; called by muse, mutect2, varscan2
- KRT73 | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59838192, COSV59838247, COSV99988578; called by muse, mutect2, varscan2
- LILRA2 | c.997A>G p.T333A | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as COSV99253503; called by muse, varscan2
- LIPF | c.1189A>T p.K397* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV99490355; called by muse, mutect2, varscan2
- LRP2 | c.12877G>C p.E4293Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV99788931; called by muse, mutect2, varscan2
- MARK4 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 81/342 reads (24%) | catalogued as rs1047483446, COSV99488413; called by muse, mutect2, varscan2
- METTL22 | c.510A>C p.R170S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV99371738; called by muse, mutect2, varscan2
- NAV2 | c.1426G>T p.G476C (on ENST00000396087 / NM_001244963.2; = p.G453C on NM_145117.5) | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100586514; called by muse, mutect2, varscan2
- NEUROD6 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99774084; called by muse, mutect2, varscan2
- NOC4L | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554287010, COSV57959223; called by muse, mutect2, varscan2
- ODAM | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 143/580 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV101258060; called by muse, mutect2, varscan2
- OR4C15 | c.356T>A p.L119Q (on ENST00000314644; = p.L65Q on NM_001001920.2) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100115757, COSV100115882; called by muse, mutect2, varscan2
- OR4K15 | c.323A>G p.D108G (on ENST00000305051; = p.D84G on NM_001005486.1) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV100521061; called by muse, mutect2, varscan2
- OSBP | c.2051A>T p.N684I | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.506); catalogued as COSV99803068; called by muse, mutect2, varscan2
- PCDH7 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62341757, COSV62344417; called by muse, mutect2, varscan2
- PDE3A | c.3293G>A p.G1098D | Missense Mutation (SNP) | VAF 97/354 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs764611561, COSV100762264; called by muse, mutect2, varscan2
- PEPD | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | catalogued as COSV99728091; called by muse, mutect2, varscan2
- PLA2G4F | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1180458014, COSV99300708, COSV99300709; called by muse, mutect2, varscan2
- PTPN21 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100162094; called by muse, mutect2, varscan2
- PWWP3A | c.1915G>A p.E639K (on ENST00000627377; = p.E638K on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV100262063; called by muse, mutect2
- RAD54L2 | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56581157, COSV56582278; called by muse, mutect2, varscan2
- RCC1L | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 104/676 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100326925; called by muse, mutect2, varscan2
- ROBO2 | c.1555A>G p.S519G | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100167412; called by muse, mutect2, varscan2
- RUSF1 | c.300G>A p.Q100= | Splice Region (SNP) | VAF 32/149 reads (21%) | catalogued as COSV100512429; called by muse, mutect2, varscan2
- SCN1B | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs786205833, COSV99386615; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- SERPING1 | c.461A>C p.Y154S | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as CM117767, CM1210628, COSV53543568, COSV99558026; called by muse, mutect2, varscan2
- SIPA1L3 | c.2731T>A p.C911S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99729129; called by muse, mutect2
- SORD | c.744C>G p.I248M | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.479); catalogued as COSV99980603; called by muse, mutect2, varscan2
- STAB2 | c.7253A>C p.E2418A | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.589); catalogued as COSV101186062; called by muse, mutect2, varscan2
- STC2 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs770708060, COSV54182271; called by muse, mutect2, varscan2
- STOML1 | c.511C>G p.Q171E | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV100381966; called by muse, mutect2, varscan2
- STYXL2 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 96/235 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1437820488, COSV99609398; called by muse, mutect2, varscan2
- TBC1D22B | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV65142532; called by muse, mutect2, varscan2
- TFAP4 | c.593A>T p.Q198L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as COSV52597418; called by muse, mutect2
- TMEM245 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV101002368; called by muse, mutect2, varscan2
- TMEM33 | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV100048866, COSV52562292; called by muse, mutect2, varscan2
- TRIM5 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as COSV99999943; called by muse, mutect2, varscan2
- TTC7A | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99766545; called by muse, mutect2, varscan2
- VN1R2 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | PolyPhen benign (0.364); catalogued as COSV100447992; called by muse, mutect2, varscan2
- WDR35 | c.2293G>A p.D765N (on ENST00000345530 / NM_001006657.2; = p.D754N on NM_020779.4) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs141979961, COSV99853252; called by muse, mutect2, varscan2
- YME1L1 | c.1817T>G p.I606S (on ENST00000326799 / NM_139312.3; = p.I549S on NM_014263.4) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV100463778; called by muse, mutect2, varscan2
- ADAM30 | c.2369dup p.*791Vfs*10 | Frame Shift Ins (INS) | VAF 14/66 reads (21%) | called by mutect2, varscan2
- ALB | c.669_685del p.C224Ifs*22 | Frame Shift Del (DEL) | VAF 59/292 reads (20%) | called by mutect2, varscan2
- AP2M1 | c.680_701del p.K227Tfs*42 | Frame Shift Del (DEL) | VAF 27/174 reads (16%) | called by mutect2, pindel, varscan2
- APOB | c.4020del p.F1340Lfs*17 | Frame Shift Del (DEL) | VAF 23/138 reads (17%) | called by mutect2, pindel, varscan2
- C17orf50 | c.283T>A p.W95R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CPT2 | c.839G>A p.S280N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- LCE1F | c.160T>A p.S54T | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.014); called by muse, mutect2
- PRMT9 | c.1141_1146+19del p.X381_splice | Splice Site (DEL) | VAF 26/306 reads (8%) | called by mutect2, pindel
- APBA1 | c.327G>C p.A109= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99596352; called by muse, mutect2, varscan2
- ARHGAP27 | c.1962C>T p.A654= (on ENST00000428638 / NM_001282290.1; = p.A313= on NM_199282.3) | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100976550; called by muse, mutect2, varscan2
- ATG5 | c.267T>A p.L89= | Silent (SNP) | VAF 20/364 reads (5%) | catalogued as COSV100576585; called by muse, mutect2
- BAZ2B | c.6276A>G p.K2092= | Silent (SNP) | VAF 15/347 reads (4%) | catalogued as COSV100600732; called by muse, mutect2
- CCDC158 | c.852T>C p.T284= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV101187273; called by muse, mutect2, varscan2
- CSMD2 | c.2202G>A p.L734= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV53879346; called by muse, mutect2, varscan2
- DCLK1 | c.276C>A p.T92= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV99711708; called by muse, varscan2
- DOCK10 | c.624G>A p.K208= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV99289950; called by muse, mutect2, varscan2
- EPHA3 | c.2328A>G p.E776= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV100345995; called by muse, mutect2, varscan2
- FHOD1 | c.141G>T p.G47= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV99264218; called by muse, mutect2, varscan2
- INSYN2A | c.991C>T p.L331= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99730395; called by muse, mutect2, varscan2
- ITGBL1 | c.813T>C p.C271= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV101095467; called by muse, mutect2, varscan2
- ITIH3 | c.85C>T p.L29= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- KALRN | c.3237C>T p.Y1079= | Silent (SNP) | VAF 87/382 reads (23%) | catalogued as COSV99565106; called by muse, mutect2, varscan2
- KRT79 | c.639G>T p.R213= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100398457; called by muse, mutect2, varscan2
- MCM3AP | c.1953C>T p.T651= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs1315970795, COSV52438732, COSV99387087; ClinVar: likely benign; called by muse, mutect2, varscan2
- MISP | c.324A>G p.T108= | Silent (SNP) | VAF 37/137 reads (27%) | catalogued as rs1223820787, COSV99296899; called by muse, mutect2, varscan2
- MYH3 | c.2178G>T p.L726= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99878358; called by muse, mutect2, varscan2
- NAV2 | c.1425G>C p.V475= (on ENST00000396087 / NM_001244963.2; = p.V452= on NM_145117.5) | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as COSV100586511; called by muse, mutect2, varscan2
- P3H3 | c.1725G>A p.Q575= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs1346030784, COSV99301342; called by muse, mutect2, varscan2
- PDCD6IP | c.1305G>A p.Q435= | Silent (SNP) | VAF 75/279 reads (27%) | catalogued as COSV100218891; called by muse, mutect2, varscan2
- REV1 | c.460C>T p.L154= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs779318152, COSV99301065; called by muse, mutect2, varscan2
- SPRY3 | c.825T>G p.S275= | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as COSV100249394; called by muse, mutect2, varscan2
- TRIM43 | c.1119T>C p.L373= | Silent (SNP) | VAF 32/243 reads (13%) | called by muse, varscan2
- AP4S1 | c.306+4240G>T | Intron (SNP) | VAF 25/327 reads (8%) | catalogued as COSV53557817, COSV99364413; called by muse, mutect2
- CTSL3P | n.270T>C | RNA (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
